Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACL2, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACL2-TTP1-A (Primary Tumor).

Sent material

- A) left lower lung lobe, biopsy
- B) lower paratracheal lymph node, removal
- C) subcarinal lymph node, removal
- D) lung ligament lymph node, removal
- E) Hilar lymph node, removal
- F) interlobar lymph node, removal

hw

CDDP-YP-ACL2-01-PR

Macroscopic report

A) lung lobe of 380 g and 16 x 11 x 7,5 cm, with smooth and focally whitish pleura. To cut the parenchyma is subtotal replaced by whitish neoformation, with blurred margins, soft - elastic and 12,5 x 7,5cm. Emphysematous the remaining parenchyma. Are isolated 3 peribronchial lymph nodes. A1 bronchial and vascular margin resection, A2 lymph node of the hilum, A3-A4 neoplasm, A5-A7 neoplasm and pleura, A8 neoplasm and lung parenchyma, A9 healthy pulmonary parenchyma.

- B) two fragments blackish of 0,5 cm and 0,8 cm the major axis
- C) one lymph node of 0,9 cm, brownish and soft elastic to the cut.

D) one anthracotico and soft elastic lymph node at the cut, of 1.1 cm in major axis.

E) anthracotico and soft elastic lymph node at the cut, of 1.2 cm in major axis.

F) fragment blackish of 0,8 cm in major axis.

Histopathological diagnosis

A-F) lung adenocarcinoma mixed (WHO 1999), bronchioloalveolar not mucinous acinar and moderately differentiated (G2) extended to 2/3 isolated peribronchial lymph nodes and lymph node of F sample. reactive nonspecific lymphadenitis with anthracosis and sinus histiocytosis in the remaining lymph nodes . Vioscerale pleura , bronchial and vascular resection margins free of neoplasia

Staging TNM : pT2,N1.

Codici SNOMED

T-28700	M-81403	M82503	C34
T-C4340	M-43000		
T-C4310	M-43000		
T-C4320	M-43000		

ICD-0-3

adenocarcinoma, w/ mixed subtypes 8255/3
Site: (R) lung, lower lobe C34.3

ICD-0-3

C34.32

hw
12/16/16

Source: NCI Genomic Data Commons file b14e31be-23d3-4e7d-aead-a04ca9650e37 (CDDP-ACL2-TTP1.7D36882E-95E2-4878-9832-3201257DA9F8.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).